Somatic mutation profile of tumor specimen TCGA-28-2513-01A (aliquot TCGA-28-2513-01A-01W-0837-08) from TCGA case TCGA-28-2513, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.6 years (25,421 days).
Specimen TCGA-28-2513-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55e23755-6dfe-4c56-86bd-01615172a7d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-2513-10A (Blood Derived Normal), aliquot TCGA-28-2513-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf9d54fb-5e3d-4d5e-b978-469a3d08ebf9

The open-access MAF lists 87 somatic variants for this specimen: 69 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 16, Nonsense Mutation 4, RNA 2, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1678G>C p.D560H (on ENST00000521381 / NM_181523.3; = p.D290H on NM_181504.4) | Missense Mutation (SNP) | VAF 53/223 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57123942, COSV57127598, COSV57130158; called by muse, mutect2, varscan2
- PTEN | c.492+1G>T p.X164_splice | Splice Site (SNP) | VAF 17/99 reads (17%) | catalogued as rs1554898242, CD020869, COSV64293587, COSV64301805, COSV64306784; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSM5 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 127/726 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs773707858, COSV100089658, COSV59370362; called by muse, mutect2, varscan2
- ALPK1 | c.2864G>A p.G955E | Missense Mutation (SNP) | VAF 38/219 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV51583510; called by muse, mutect2, varscan2
- ARAP2 | c.1883C>G p.T628S | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.407); catalogued as COSV58282727, COSV58284687; called by muse, mutect2, varscan2
- BTN3A2 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs780178954, COSV62687000; called by muse, mutect2, varscan2
- CCDC96 | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 23/86 reads (27%) | catalogued as COSV59508423; called by muse, mutect2, varscan2
- CFAP54 | c.5672G>A p.R1891Q | Missense Mutation (SNP) | VAF 218/1007 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.251); catalogued as rs367592020; called by muse, mutect2, varscan2
- CNGA4 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 70/251 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs759024495, COSV66005499; called by muse, mutect2, varscan2
- COL14A1 | c.3808G>A p.V1270I | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.217); catalogued as COSV52850695; called by muse, mutect2, varscan2
- CSAG1 | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 257/1227 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1556830737, COSV63400002; called by muse, mutect2, varscan2
- CTAGE1 | c.977A>T p.N326I | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as COSV66943185; called by muse, mutect2, varscan2
- DDI1 | c.592C>G p.L198V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV56372946; called by muse, mutect2, varscan2
- DMD | c.4580G>A p.R1527H | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63736457; called by muse, mutect2, varscan2
- ENPEP | c.1158G>T p.R386S | Missense Mutation (SNP) | VAF 63/253 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1263451725, COSV54448784; called by muse, mutect2, varscan2
- FAN1 | c.139T>C p.C47R | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62950173; called by muse, mutect2, varscan2
- FAT2 | c.8767G>A p.E2923K | Missense Mutation (SNP) | VAF 163/769 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.685); catalogued as rs777011886, COSV55816581; called by muse, mutect2, varscan2
- FBN3 | c.2656G>A p.V886I | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs758594630, COSV54455168; called by muse, mutect2, varscan2
- FCGBP | c.9400G>A p.A3134T | Missense Mutation (SNP) | VAF 57/660 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.543); catalogued as rs764099590; called by muse, mutect2
- FGFBP1 | c.334T>C p.Y112H | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52586266; called by muse, mutect2, varscan2
- FLG2 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 55/303 reads (18%) | catalogued as rs200529004, COSV66167566; called by muse, mutect2, varscan2
- G6PD | c.1424A>G p.E475G | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV63702720; called by mutect2, varscan2
- GTPBP3 | c.739C>A p.R247S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV50174594, COSV50178561; called by muse, mutect2, varscan2
- HMCN1 | c.14510G>A p.R4837Q | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs752242653, COSV54888710; called by muse, mutect2, varscan2
- INTS6L | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 96/555 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as COSV66083993; called by muse, mutect2, varscan2
- ITGB4 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.458); catalogued as rs144968507; called by muse, mutect2, varscan2
- KCNK10 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 69/195 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); catalogued as rs373732858; called by muse, mutect2, varscan2
- MAGEB2 | c.70G>T p.G24C | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.275); catalogued as rs759205287, COSV66780507; called by muse, mutect2, varscan2
- MAGEB4 | c.355T>A p.F119I | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV64396869; called by muse, mutect2, varscan2
- MAGED1 | c.1333T>A p.S445T | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.441); catalogued as COSV58514869; called by muse, mutect2, varscan2
- MKS1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.07); catalogued as rs753620277, COSV58303259; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC16 | c.18682C>A p.L6228I | Missense Mutation (SNP) | VAF 112/988 reads (11%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.06); catalogued as COSV67455841; called by muse, mutect2, varscan2
- MYH1 | c.5116G>A p.A1706T | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as rs779544532, COSV56845883; called by muse, mutect2, varscan2
- MYH2 | c.5002C>T p.R1668W | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs569489518, COSV55431886, COSV55435762; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NSMAF | c.1281-1G>A p.X427_splice | Splice Site (SNP) | VAF 18/144 reads (13%) | catalogued as COSV50685226; called by muse, mutect2, varscan2
- OASL | c.821G>C p.C274S | Missense Mutation (SNP) | VAF 105/389 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771301337, COSV57477751; called by muse, mutect2, varscan2
- OR5D14 | c.739C>A p.L247M | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV59455852; called by muse, mutect2, varscan2
- OR6C3 | c.886C>A p.Q296K | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV65570857; called by muse, varscan2
- OR8A1 | c.248T>A p.V83E | Missense Mutation (SNP) | VAF 182/700 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.033); catalogued as COSV52508289; called by muse, mutect2, varscan2
- OTC | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV50000954; called by muse, mutect2, varscan2
- PCDH19 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55260143; called by muse, mutect2, varscan2
- PIK3AP1 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.437); catalogued as rs1017199374, COSV59531354; called by muse, mutect2, varscan2
- POLA1 | c.2747G>A p.R916Q | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs771556456, COSV66884935; called by muse, mutect2, varscan2
- PPID | c.399T>G p.F133L | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56987396; called by muse, mutect2, varscan2
- PPP1R3A | c.1825G>A p.A609T | Missense Mutation (SNP) | VAF 108/641 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144397367, COSV52887227; called by muse, mutect2, varscan2
- PREX1 | c.1817G>A p.S606N | Missense Mutation (SNP) | VAF 109/726 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1024666868, COSV64249943; called by muse, mutect2, varscan2
- PRSS35 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 70/239 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs757842601, COSV63800328; called by muse, mutect2, varscan2
- PTPRB | c.4988G>A p.R1663Q | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as rs139546127, COSV54237615; called by muse, mutect2, varscan2
- PTPRR | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 175/511 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.109); catalogued as rs775822570, COSV104392843, COSV51728386; called by muse, mutect2, varscan2
- RABGEF1 | c.259A>T p.S87C (on ENST00000439720 / NM_001287061.2; = p.S74C on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as COSV53161529; called by muse, mutect2, varscan2
- RBM47 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as rs754268660, COSV55932469; called by muse, mutect2, varscan2
- ROCK1 | c.3160A>T p.K1054* | Nonsense Mutation (SNP) | VAF 123/717 reads (17%) | catalogued as COSV67695250; called by muse, mutect2, varscan2
- RTBDN | c.232C>T p.R78C (on ENST00000393233 / NM_001270444.1; = p.R110C on NM_031429.2) | Missense Mutation (SNP) | VAF 79/439 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs781025146, COSV100530853, COSV59806076; called by muse, mutect2, varscan2
- SERPINB4 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 51/296 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs200350590, COSV100346018, COSV61984604; called by muse, mutect2, varscan2
- SHANK2 | c.4169G>A p.R1390H | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as rs781838189, COSV99571443; called by muse, mutect2
- TMEM150C | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as COSV71388856; called by muse, mutect2, varscan2
- TRPS1 | c.3312C>A p.F1104L (on ENST00000220888 / NM_001330599.2; = p.F1117L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as COSV55232664, COSV55266777; called by muse, mutect2, varscan2
- TTN | c.49088A>C p.E16363A (on ENST00000591111; = p.E8939A on NM_003319.4) | Missense Mutation (SNP) | VAF 19/110 reads (17%) | PolyPhen benign (0.205); catalogued as COSV59964135; called by muse, mutect2, varscan2
- UBA52 | c.13G>C p.V5L | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV55889284; called by muse, mutect2
- YIPF5 | c.680T>G p.F227C | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50822985; called by muse, mutect2, varscan2
- ZBBX | c.1000C>G p.L334V | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV56785919, COSV56789670; called by muse, mutect2, varscan2
- ZFC3H1 | c.384T>G p.S128R | Missense Mutation (SNP) | VAF 164/330 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100350322; called by mutect2, varscan2
- ZFHX3 | c.10321G>T p.E3441* | Nonsense Mutation (SNP) | VAF 51/240 reads (21%) | catalogued as COSV51713532, COSV51730707; called by muse, mutect2, varscan2
- ZFYVE9 | c.1006G>T p.G336C | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.319); catalogued as rs770706827, COSV55092219; called by muse, mutect2, varscan2
- ZNF804A | c.2314C>T p.R772C | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs762537446, COSV56437409; called by muse, mutect2, varscan2
- ACACA | c.1534G>C p.D512H | Missense Mutation (SNP) | VAF 62/211 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- POTEF | c.2496G>A p.M832I | Missense Mutation (SNP) | VAF 50/1134 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); called by muse, mutect2
- REPS1 | c.1245del p.Q416Rfs*19 | Frame Shift Del (DEL) | VAF 85/476 reads (18%) | called by mutect2, pindel, varscan2
- ZNF765 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 215/410 reads (52%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.839); called by muse, varscan2
- ABCC5 | c.3387G>T p.A1129= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV55588547; called by mutect2, varscan2
- CDX4 | c.72C>T p.D24= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs775744896, COSV65171484; called by muse, mutect2, varscan2
- CNTNAP3 | c.1911C>A p.G637= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- DSC2 | c.135C>T p.A45= | Silent (SNP) | VAF 72/396 reads (18%) | catalogued as rs749323567, COSV51862606; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- EIF4G1 | c.3249G>A p.Q1083= (on ENST00000346169 / NM_198241.3; = p.Q888= on NM_004953.5) | Silent (SNP) | VAF 42/166 reads (25%) | catalogued as rs1282999964, COSV59989980; called by muse, mutect2, varscan2
- EP400 | c.5364G>A p.L1788= | Silent (SNP) | VAF 66/283 reads (23%) | catalogued as COSV57768315; called by muse, mutect2, varscan2
- FLG | c.11706C>T p.P3902= | Silent (SNP) | VAF 35/139 reads (25%) | catalogued as rs147335121; called by muse, mutect2, varscan2
- ITGAM | c.1395C>T p.D465= | Silent (SNP) | VAF 117/649 reads (18%) | catalogued as rs377110507; called by muse, mutect2, varscan2
- LRRN4CL | c.297C>T p.R99= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1196550385, COSV54017233; called by muse, mutect2
- MYLK | c.5574C>T p.D1858= | Silent (SNP) | VAF 76/338 reads (22%) | catalogued as COSV60607698, COSV60623636; called by muse, mutect2, varscan2
- NRXN1 | c.1953C>T p.G651= | Silent (SNP) | VAF 140/739 reads (19%) | catalogued as COSV58443726; called by muse, mutect2, varscan2
- OR10A4 | c.247C>T p.L83= | Silent (SNP) | VAF 52/836 reads (6%) | called by muse, mutect2
- PKHD1L1 | c.9588G>A p.E3196= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV65740301, COSV65748782; called by mutect2, varscan2
- PSD4 | c.246C>T p.D82= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs147089589; called by mutect2, varscan2
- SNN | c.153G>A p.V51= | Silent (SNP) | VAF 28/166 reads (17%) | catalogued as rs368425651; called by muse, varscan2
- ZNF787 | c.36G>A p.P12= | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as rs1248577053, COSV54418089; called by muse, mutect2, varscan2
- MIR517A | n.24G>T | RNA (SNP) | VAF 47/288 reads (16%) | called by muse, mutect2, varscan2
- TUBB7P | n.1168C>T | RNA (SNP) | VAF 305/346 reads (88%) | catalogued as rs17799221; called by muse, mutect2, varscan2
